Somatic mutation profile of tumor specimen TCGA-DD-A119-01A (aliquot TCGA-DD-A119-01A-11D-A12Z-10) from TCGA case TCGA-DD-A119, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 40.0 years (14,613 days).
Specimen TCGA-DD-A119-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f9a21bde-8da8-4cef-abfc-94f6f33c5780.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-A119-10A (Blood Derived Normal), aliquot TCGA-DD-A119-10A-01D-A12Z-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/95fe78e8-3445-4e3c-b3bc-81032c88e17b

The open-access MAF lists 68 somatic variants for this specimen: 51 protein-altering or splice-affecting, 16 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, Silent 16, Nonsense Mutation 2, RNA 1, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.101G>T p.G34V | Missense Mutation (SNP) | VAF 12/188 reads (6%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28931589, COSV62687976, COSV62688267, COSV62692205; ClinVar: likely pathogenic / uncertain significance / pathogenic; called by muse, mutect2
- PEX6 | c.2440C>T p.R814* | Nonsense Mutation (SNP) | VAF 16/167 reads (10%) | catalogued as rs267608241, CM100015, COSV55102082; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AKNAD1 | c.496C>T p.P166S | Missense Mutation (SNP) | VAF 14/298 reads (5%) | SIFT tolerated (0.43); PolyPhen benign (0.011); catalogued as COSV62198630; called by muse, mutect2
- APOM | c.83A>C p.Q28P | Missense Mutation (SNP) | VAF 35/189 reads (19%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV52990795; called by muse, mutect2, varscan2
- ARHGAP10 | c.2132C>A p.P711H | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV60599534; called by muse, mutect2, varscan2
- ASXL2 | c.3869G>C p.S1290T | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.026); catalogued as COSV55458958; called by muse, mutect2
- ATL3 | c.1585G>T p.A529S | Missense Mutation (SNP) | VAF 93/225 reads (41%) | SIFT tolerated (0.82); PolyPhen benign (0.055); catalogued as COSV60296313; called by muse, mutect2, varscan2
- CCR10 | c.953G>A p.R318H | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1391271591, COSV52850643; called by muse, mutect2, varscan2
- CDK5RAP2 | c.5486A>T p.H1829L | Missense Mutation (SNP) | VAF 30/229 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.058); catalogued as COSV62574365; called by muse, mutect2, varscan2
- COL6A5 | c.6626T>C p.I2209T (on ENST00000312481; = p.I2205T on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/250 reads (14%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.011); catalogued as COSV55202129; called by muse, mutect2, varscan2
- DCDC1 | c.5261C>G p.A1754G (on ENST00000597505 / NM_001367979.1; = p.A861G on NM_020869.3) | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT tolerated (0.38); PolyPhen benign (0.272); catalogued as COSV57999312; called by muse, mutect2, varscan2
- DLG2 | c.2489T>C p.F830S | Missense Mutation (SNP) | VAF 48/450 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54645099; called by muse, mutect2, varscan2
- DMXL1 | c.1193A>C p.K398T | Missense Mutation (SNP) | VAF 83/317 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV100224320; called by muse, varscan2
- ENGASE | c.527G>C p.W176S | Missense Mutation (SNP) | VAF 43/102 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV56135547; called by muse, mutect2, varscan2
- FGF6 | c.415G>A p.V139I | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.014); catalogued as rs759669908, COSV57403617; called by muse, mutect2, varscan2
- FIGN | c.644A>G p.H215R | Missense Mutation (SNP) | VAF 44/155 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.026); catalogued as COSV60766742; called by muse, mutect2, varscan2
- GALNT6 | c.35G>T p.R12L | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.062); catalogued as COSV100695511; called by muse, mutect2
- GPR68 | c.952G>A p.E318K | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.03); catalogued as COSV53176341; called by muse, mutect2
- HMGXB4 | c.727A>G p.S243G | Missense Mutation (SNP) | VAF 15/120 reads (13%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV53334038; called by muse, mutect2, varscan2
- HTR2B | c.797C>T p.T266I | Missense Mutation (SNP) | VAF 54/138 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); catalogued as COSV51449823; called by muse, mutect2, varscan2
- IQCB1 | c.472G>T p.E158* | Nonsense Mutation (SNP) | VAF 92/248 reads (37%) | catalogued as COSV100181958, COSV60437555; called by muse, mutect2, varscan2
- ITSN1 | c.147dup p.Q50Sfs*17 | Frame Shift Ins (INS) | VAF 103/238 reads (43%) | catalogued as rs746959118; called by mutect2, varscan2
- JAK1 | c.2443C>T p.P815S | Missense Mutation (SNP) | VAF 42/132 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV61091109; called by muse, mutect2, varscan2
- KCNB2 | c.310C>T p.R104W | Missense Mutation (SNP) | VAF 21/299 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV73050150; called by muse, mutect2
- KIF4B | c.748A>C p.T250P | Missense Mutation (SNP) | VAF 19/266 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70529345, COSV70529492; called by muse, mutect2
- KLHDC7A | c.1895G>A p.R632H | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as rs745970080, COSV68769785; called by muse, mutect2, varscan2
- KRTAP26-1 | c.62A>C p.H21P | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.078); catalogued as COSV62128801; called by muse, mutect2, varscan2
- LRRC24 | c.1267G>A p.A423T | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0.01); catalogued as COSV52879494; called by muse, mutect2
- LRRC3B | c.577G>T p.D193Y | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV67521134; called by muse, mutect2
- MED24 | c.2104C>T p.P702S | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.999); catalogued as rs755768525, COSV62418721, COSV62420675; called by muse, mutect2, varscan2
- MEP1B | c.1000C>A p.P334T | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as rs1334949015, COSV52496062; called by muse, mutect2, varscan2
- MTMR4 | c.416T>C p.L139P | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.61); catalogued as COSV60200672; called by muse, mutect2, varscan2
- MYO18A | c.5561A>T p.K1854M | Missense Mutation (SNP) | VAF 55/144 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62866485; called by muse, varscan2
- MYO9A | c.7247G>A p.R2416Q | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.01); catalogued as rs765535109, COSV61848252; called by mutect2, varscan2
- NBEAL2 | c.5209A>T p.M1737L | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.254); catalogued as COSV52757849; called by muse, mutect2, varscan2
- NLRP5 | c.3155C>T p.A1052V | Missense Mutation (SNP) | VAF 19/135 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.079); catalogued as rs778328871, COSV66764528; called by muse, mutect2, varscan2
- OR9A4 | c.920G>T p.R307L | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as COSV71885167, COSV71885465; called by muse, mutect2, varscan2
- QRSL1 | c.1475A>G p.K492R | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as rs746261877, COSV64688743; called by muse, mutect2
- RIMS1 | c.199T>C p.C67R | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV53454863, COSV53456536; called by muse, mutect2, varscan2
- SEPSECS | c.593T>C p.L198P | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754956032, COSV57205610; called by mutect2, varscan2
- SEZ6L | c.2839G>T p.A947S | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.804); catalogued as COSV50664639; called by muse, mutect2, varscan2
- SIPA1L2 | c.1081G>T p.A361S | Missense Mutation (SNP) | VAF 45/67 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53390632; called by muse, mutect2, varscan2
- SLC1A6 | c.1009G>A p.G337S | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.009); catalogued as COSV55669809; called by muse, mutect2
- SLC30A6 | c.97A>G p.K33E | Missense Mutation (SNP) | VAF 96/257 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as COSV50872544; called by muse, mutect2, varscan2
- SLK | c.263A>G p.H88R | Missense Mutation (SNP) | VAF 34/117 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59825526; called by muse, mutect2, varscan2
- SPTLC3 | c.613T>A p.L205M | Missense Mutation (SNP) | VAF 50/147 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.091); catalogued as COSV65465597; called by muse, mutect2, varscan2
- STMN2 | c.212T>C p.L71S | Missense Mutation (SNP) | VAF 32/224 reads (14%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.761); catalogued as rs1409002840, COSV55219518; called by muse, mutect2, varscan2
- ZFHX4 | c.83A>G p.D28G | Missense Mutation (SNP) | VAF 25/260 reads (10%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.453); catalogued as rs1184061424, COSV50811787; called by muse, mutect2, varscan2
- IGHV3-7 | c.21G>T p.W7C | Missense Mutation (SNP) | VAF 97/277 reads (35%) | SIFT tolerated, low confidence (0.18); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRRC8A | c.1412_1413del p.L471Qfs*13 | Frame Shift Del (DEL) | VAF 10/35 reads (29%) | called by mutect2, pindel, varscan2
- MED24 | c.1880A>C p.H627P | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- ACSL1 | c.1860G>A p.S620= | Silent (SNP) | VAF 33/107 reads (31%) | catalogued as rs375524934; called by muse, mutect2, varscan2
- ALS2CL | c.1374G>A p.R458= | Silent (SNP) | VAF 49/135 reads (36%) | catalogued as rs1050047506, COSV59671404; called by muse, mutect2, varscan2
- DOCK7 | c.3675A>C p.S1225= (on ENST00000635253 / NM_001367561.1; = p.S1194= on NM_033407.3) | Silent (SNP) | VAF 13/123 reads (11%) | catalogued as COSV52005807; called by muse, mutect2
- H1-7 | c.681G>C p.P227= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as COSV58602062, COSV58602149; called by muse, mutect2, varscan2
- KANK4 | c.1692G>T p.V564= | Silent (SNP) | VAF 21/137 reads (15%) | catalogued as COSV62986808; called by muse, mutect2, varscan2
- KIF2B | c.828C>T p.N276= | Silent (SNP) | VAF 35/101 reads (35%) | catalogued as rs1417694993, COSV52130429; called by muse, mutect2, varscan2
- MMP14 | c.225A>G p.Q75= | Silent (SNP) | VAF 4/39 reads (10%) | catalogued as COSV61288280; called by muse, mutect2, varscan2
- OPRL1 | c.891C>T p.A297= | Silent (SNP) | VAF 33/84 reads (39%) | catalogued as rs764583670, COSV61091745; called by muse, mutect2, varscan2
- PCDHA11 | c.1512G>A p.S504= | Silent (SNP) | VAF 12/148 reads (8%) | catalogued as COSV56500484, COSV56538172; called by muse, mutect2
- SERTAD2 | c.150C>T p.N50= | Silent (SNP) | VAF 21/197 reads (11%) | catalogued as COSV57640255; called by muse, mutect2, varscan2
- SH3BP5L | c.1008G>C p.L336= | Silent (SNP) | VAF 11/75 reads (15%) | catalogued as COSV63539210; called by muse, mutect2, varscan2
- SLC38A10 | c.1260G>A p.L420= | Silent (SNP) | VAF 15/47 reads (32%) | catalogued as rs1567931578, COSV55845497; called by muse, mutect2, varscan2
- SNAP91 | c.1194A>T p.A398= | Silent (SNP) | VAF 100/164 reads (61%) | catalogued as COSV52122373; called by muse, mutect2, varscan2
- TDRKH | c.507A>G p.L169= | Silent (SNP) | VAF 70/466 reads (15%) | catalogued as COSV64316335; called by muse, mutect2, varscan2
- TEX101 | c.9C>T p.T3= (on ENST00000598265 / NM_001130011.3; = p.T21= on NM_031451.4) | Silent (SNP) | VAF 63/145 reads (43%) | catalogued as rs149972012; called by muse, mutect2, varscan2
- TRRAP | c.11475C>T p.L3825= (on ENST00000359863 / NM_001244580.1; = p.L3796= on NM_003496.3) | Silent (SNP) | VAF 11/57 reads (19%) | catalogued as rs762119583, COSV62816127; called by muse, mutect2, varscan2
- OR2W5 | n.584T>A | RNA (SNP) | VAF 12/152 reads (8%) | called by muse, mutect2
